Somatic mutation profile of tumor specimen 0DVPOK from CCDI case PBCMNI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 6.5 years (2,367 days).
Specimen 0DVPOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9507876-5904-4f5e-be0f-07872baf5717.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPP4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77c1f5f0-b9f9-4893-a802-08876e9660a6

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 3, Silent 2, Nonsense Mutation 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC12 | c.10132G>A p.G3378S (on ENST00000379442; = p.G3235S on NM_001164462.1) | Missense Mutation (SNP) | VAF 150/1397 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.86); catalogued as rs773417421, COSV65198954; called by muse, varscan2
- BCOR | c.4352dup p.E1452Gfs*9 (on ENST00000378444 / NM_001123385.2; = p.E1418Gfs*9 on NM_017745.6) | Frame Shift Ins (INS) | VAF 331/479 reads (69%) | called by mutect2, pindel, varscan2
- GARNL3 | c.465C>A p.Y155* | Nonsense Mutation (SNP) | VAF 267/770 reads (35%) | called by muse, mutect2, varscan2
- GRIA1 | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 52/1578 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2
- KIAA0753 | c.2384G>T p.R795I | Missense Mutation (SNP) | VAF 223/563 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHACTR3 | c.689G>T p.S230I | Missense Mutation (SNP) | VAF 294/1258 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 18/654 reads (3%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- ZSCAN31 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 38/782 reads (5%) | called by muse, mutect2
- CYP4B1 | c.1437C>T p.D479= | Silent (SNP) | VAF 313/628 reads (50%) | called by muse, mutect2, varscan2
- MUC5B | c.13782G>A p.P4594= | Silent (SNP) | VAF 189/569 reads (33%) | catalogued as rs752326374; called by muse, mutect2, varscan2
- CUX2 | c.*86G>A | 3'UTR (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- FBXL19 | c.*35G>C | 3'UTR (SNP) | VAF 132/442 reads (30%) | catalogued as rs932485074; called by mutect2, varscan2
- KLHL33 | c.-30C>A | 5'UTR (SNP) | VAF 201/397 reads (51%) | catalogued as COSV60725862; called by muse, mutect2, varscan2
- LHFPL3 | c.*94G>A | 3'UTR (SNP) | VAF 251/825 reads (30%) | catalogued as rs574268515; called by muse, mutect2, varscan2
